Surgical pathology report (de-identified scan), TCGA case TCGA-RY-A83X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of California San Francisco, specimen TCGA-RY-A83X-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Age:) Sex: Female
Soc. Sec. #: [REDACTED] Location:
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, right frontal lobe, biopsy: Oligodendroglioma, WHO Grade II; see comment.
B. Brain, right frontal lobe, resection: Oligodendroglioma, WHO Grade II; see comment.
C. Brain, right frontal lobe, CUSA resection: Oligodendroglioma, WHO Grade II; see comment.

*ICD-O-3
Oligodendroglioma, grade II 9450/3
Site ~~Cereb~~ Brain Supratentorial C71.0
Path B Brain, frontal lobe C71.1*

COMMENT:

The morphologic features are typical of oligodendroglioma. Up to 2 mitoses/10 HPF are noted.

Immunohistochemistry for **IDH-1** was performed and evaluated on block A2 and is **positive** (cytoplasmic staining). Immunohistochemistry for MIB-1 on block A2 shows a labeling index of approximately 3-4%.

Fluorescence in situ hybridization for 1p19q will be performed on block B1 at the and the results will be reported separately.

Intraoperative Diagnosis

FS1 (A) Brain, right frontal, biopsy: Oligoastrocytoma versus oligodendroglioma, WHO Grade II (tissue section and cytology). agrees.

Gross Description

The specimen is received in three parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh.

Part A is additionally labeled "tumor, FS + perm," consists of one unoriented, irregular, pale-tan, rubbery, firm tissue fragment (1.1 x 0.5 x 0.2 cm). A touch prep is created for intraoperative consultation. A representative section is frozen for frozen section diagnosis 1. The specimen is entirely

[page 2 of 2]
submitted as follows:

A1: Frozen section remnant.
A2: Remainder of specimen.

Part B, additionally labeled "tumor," consists of two white, irregular, unoriented soft tissue fragments (1.3 x 0.5 x 0.3 cm in aggregate). The specimen is submitted intact in cassette B1.

Part C, additionally labeled "CUSA contents," consists of multiple soft, pink-white, irregular, unoriented soft tissue fragments (8 x 3 x 1 cm in aggregate). Representative sections are submitted in cassettes C1-C8.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a -year-old woman with no additional history provided. Review of electronic medical records indicates that the patient has a right frontal lobe nonenhancing mass centered in the middle frontal gyrus measuring 4.9 x 3.7 x 2.4 cm with imaging features compatible with a primary glial neoplasm. She now undergoes resection of this mass.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

/Pathology Resident

Signed: /Pathologist

Addendum

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out
By:

Addendum Comment

has reviewed the case and agrees with the diagnosis.

Pathologist

Electronically signed out on

IHPAA Discrepancy		✓

Source: NCI Genomic Data Commons file c6971ee3-ece8-4633-b67f-c3ea0901de60 (TCGA-RY-A83X.0964A173-152D-4C42-BBBC-19AFB12DC8E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).